TARGET case TARGET-30-PANBMJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fdfb389d-eb9a-5014-b391-9cd5f908720d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 3,776 days (10.3 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C47.6; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of trunk, NOS; Classification of tumor: primary; Age at diagnosis: 2.7 years (993 days); Year of diagnosis: 2004; Days to last follow up: 3,776 days (10.3 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ADVL0921.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ADVL0813.
   Treatment given: Protocol identifier: ALTE05N1.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: P9641.
   Treatment given: Protocol identifier: A3973.

Follow-up (2 entries)
- Days to follow up: 577 days (1.6 years); Days to first event: 577 days (1.6 years); First event: Relapse.
- Days to follow up: 3,776 days (10.3 years); Year of follow up: 2014.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (3 samples)
- Sample TARGET-30-PANBMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PANBMJ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PANBMJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3776
- Protocol: ANBL00B1, P9641, A3973, ANBL0032, ALTE05N1, ADVL0813, ADVL0921
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- MKI: Low
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO Description: Peripheral nerves and Autonomic nervous system of trunk, NOS Peripheral nerves and Autonomic nervous system of (see list under C47): . Back . Flank . Trunk Lumbar nerve
- Site of Relapse: Primary Site
